Somatic mutation profile of tumor specimen CDDP-ABKE-TTP1-A (aliquot CDDP-ABKE-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABKE, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62 years.
Specimen CDDP-ABKE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68579e61-bd89-4b81-9b5d-9d755ff04bfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABKE-NB1-A (Blood Derived Normal), aliquot CDDP-ABKE-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08b0c5eb-2dca-40b9-bf5f-e68c9c7e061d

The open-access MAF lists 158 somatic variants for this specimen: 110 protein-altering or splice-affecting, 22 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 22, Intron 12, Frame Shift Del 7, Nonsense Mutation 5, Splice Site 5, 5'Flank 4, 5'UTR 3, 3'Flank 3, RNA 2, 3'UTR 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.374+1A>G p.X125_splice | Splice Site (SNP) | VAF 39/91 reads (43%) | hotspot (GDC flag); catalogued as rs1131690951, CS021376, COSV58820569; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCF2 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as rs1420632007, COSV55184859; called by muse, mutect2, varscan2
- AMER1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 80/108 reads (74%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.777); catalogued as rs764161315, COSV57664386; called by muse, mutect2, varscan2
- AMZ1 | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as rs1191356349, COSV56688297; called by muse, mutect2, varscan2
- APBB2 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 49/256 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs951466767, COSV55957897; called by muse, mutect2, varscan2
- ARL11 | c.20G>C p.R7T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV56291737; called by muse, mutect2, varscan2
- C7 | c.281del p.X94_splice | Splice Site (DEL) | VAF 28/88 reads (32%) | catalogued as CS056081; called by mutect2, pindel, varscan2
- CCER1 | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62647887; called by muse, mutect2, varscan2
- CDH11 | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51770120; called by muse, mutect2, varscan2
- CDKN2AIP | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs772372032, COSV56627668; called by muse, mutect2, varscan2
- CEP290 | c.2510C>G p.S837C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as COSV58354061; called by muse, mutect2, varscan2
- CFAP206 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs561570371, COSV51535620, COSV99739138; called by muse, mutect2, varscan2
- COL14A1 | c.1966T>A p.L656M | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52862126; called by muse, mutect2, varscan2
- COL21A1 | c.207A>G p.I69M | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55172708; called by muse, mutect2, varscan2
- CSNK1G1 | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57312197; called by muse, varscan2
- DMTN | c.727A>G p.K243E | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV56113670; called by muse, mutect2, varscan2
- EPB41L2 | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61357488; called by muse, mutect2, varscan2
- EPRS1 | c.981A>T p.K327N | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV65100470; called by muse, mutect2, varscan2
- FAT1 | c.5464A>T p.I1822F | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71675224; called by muse, mutect2, varscan2
- FBN1 | c.6427A>T p.I2143F | Missense Mutation (SNP) | VAF 113/258 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs779072283, COSV57324773; called by muse, mutect2, varscan2
- FHOD1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as COSV50764694; called by muse, mutect2, varscan2
- FLNC | c.6408G>T p.E2136D | Missense Mutation (SNP) | VAF 21/469 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV100368088; called by muse, mutect2
- FRY | c.512T>A p.I171N | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV66574951; called by muse, mutect2, varscan2
- GABRB3 | c.1355C>A p.S452Y | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54675152; called by muse, mutect2, varscan2
- GOLIM4 | c.1678G>C p.D560H | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58330924; called by muse, mutect2, varscan2
- H3C8 | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV59953073, COSV59953405; called by muse, mutect2, varscan2
- HCRTR2 | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV63797576; called by muse, mutect2, varscan2
- HCRTR2 | c.1286T>G p.I429R | Missense Mutation (SNP) | VAF 109/319 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as COSV63797581; called by muse, mutect2, varscan2
- HSF1 | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as COSV60048838; called by muse, mutect2
- IL12B | c.921C>A p.S307R | Missense Mutation (SNP) | VAF 106/407 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as COSV51455604; called by muse, mutect2, varscan2
- IPO4 | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55781069; called by muse, mutect2, varscan2
- IREB2 | c.1996C>A p.P666T | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765725005, COSV51924989; called by muse, mutect2, varscan2
- JAK1 | c.800A>C p.K267T | Missense Mutation (SNP) | VAF 83/157 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV61094353; called by muse, mutect2, varscan2
- KIAA0825 | c.2107T>C p.W703R | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56956290; called by muse, mutect2, varscan2
- LCE3D | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 106/576 reads (18%) | catalogued as rs138117867; called by muse, mutect2, varscan2
- LLGL2 | c.236T>A p.I79N | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV51377921; called by muse, mutect2, varscan2
- MAD1L1 | c.1847A>T p.Q616L | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1193808551, COSV56241306; called by muse, mutect2, varscan2
- MAML2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758109905, COSV73263326; called by muse, mutect2, varscan2
- MAML2 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 103/189 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs749258668, COSV73263187, COSV73264236; called by muse, mutect2, varscan2
- MUL1 | c.1014C>G p.I338M | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV51642541; called by muse, mutect2, varscan2
- MYOCD | c.2813G>A p.W938* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV58508054; called by muse, varscan2
- NAT16 | c.176C>G p.T59R | Missense Mutation (SNP) | VAF 89/292 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as COSV55865223; called by muse, mutect2, varscan2
- NAV3 | c.2601G>T p.Q867H | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV57098045, COSV57110468; called by muse, mutect2, varscan2
- NAV3 | c.2602A>T p.R868* | Nonsense Mutation (SNP) | VAF 20/104 reads (19%) | catalogued as COSV57098068; called by muse, mutect2, varscan2
- OR2M7 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.795); catalogued as COSV58739904; called by muse, mutect2, varscan2
- OR4C16 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58943262; called by muse, mutect2, varscan2
- OR4X1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV60723418; called by muse, mutect2, varscan2
- OR8D2 | c.329C>A p.A110E | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV62488766; called by muse, mutect2, varscan2
- PC | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63081823; called by muse, mutect2, varscan2
- PGBD4 | c.548T>C p.L183S | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV56628527; called by muse, mutect2, varscan2
- PHRF1 | c.3275G>T p.R1092L (on ENST00000264555 / NM_001286581.2; = p.R1091L on NM_020901.4) | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs1199430082, COSV52752310; called by muse, mutect2
- PLEKHH1 | c.3969G>A p.M1323I | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53614949; called by muse, mutect2, varscan2
- PLEKHH2 | c.387G>C p.K129N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56753527, COSV56757868; called by muse, mutect2, varscan2
- PRR27 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60641091; called by muse, mutect2, varscan2
- RAD54L2 | c.3407C>T p.S1136L | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.281); catalogued as COSV56580283; called by muse, mutect2, varscan2
- RBM44 | c.461A>T p.D154V (on ENST00000611254; = p.D788V on NM_001080504.2) | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57631881; called by muse, mutect2, varscan2
- RMDN2 | c.251C>A p.T84K | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV63340513; called by muse, mutect2, varscan2
- SCN1A | c.5304T>G p.S1768R (on ENST00000303395 / NM_001202435.3; = p.S1757R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/382 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57679558; called by muse, mutect2, varscan2
- SGCD | c.728C>G p.P243R (on ENST00000435422 / NM_001128209.2; = p.P244R on NM_000337.5) | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.833); catalogued as COSV61912575; called by muse, mutect2, varscan2
- SLC28A2 | c.1799A>T p.N600I | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV61664741; called by muse, mutect2, varscan2
- SLITRK6 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68391025; called by muse, mutect2, varscan2
- SOD2 | c.492T>A p.C164* | Nonsense Mutation (SNP) | VAF 34/106 reads (32%) | catalogued as COSV61623189; called by muse, mutect2, varscan2
- SRRT | c.2149C>G p.L717V | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53819842; called by muse, mutect2, varscan2
- SYCP1 | c.2021C>T p.S674L | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV65699705; called by muse, mutect2, varscan2
- SYNE3 | c.2227C>A p.L743M | Missense Mutation (SNP) | VAF 77/394 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.952); catalogued as COSV62078052, COSV62081031; called by muse, mutect2, varscan2
- TAF12 | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); catalogued as COSV56040504; called by muse, mutect2, varscan2
- TBX3 | c.1304C>G p.S435* (on ENST00000257566 / NM_016569.4; = p.S415* on NM_005996.4) | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as COSV57473840; called by muse, mutect2, varscan2
- TECTA | c.3029T>G p.V1010G | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.096); catalogued as COSV50755927; called by muse, mutect2
- TENM4 | c.7660C>A p.P2554T | Missense Mutation (SNP) | VAF 131/295 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV53650967; called by muse, mutect2, varscan2
- TMEM232 | c.125G>T p.R42M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV70271563; called by muse, mutect2, varscan2
- TNFAIP2 | c.1360C>A p.L454M | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100280927; called by muse, mutect2, varscan2
- TNFAIP6 | c.92T>A p.L31H | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54641746; called by muse, mutect2, varscan2
- TNFRSF8 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs748264573, COSV55798856; called by muse, mutect2, varscan2
- TROAP | c.2150C>G p.S717W | Missense Mutation (SNP) | VAF 62/209 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV57745210; called by muse, mutect2, varscan2
- TRPM1 | c.1808C>A p.P603H | Missense Mutation (SNP) | VAF 76/304 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV56638599; called by muse, mutect2, varscan2
- TRPM6 | c.4318C>G p.L1440V | Missense Mutation (SNP) | VAF 215/389 reads (55%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV100666241, COSV62517359; called by muse, mutect2, varscan2
- TSPAN17 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV53781221; called by muse, mutect2, varscan2
- TTPA | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV52647633; called by muse, mutect2, varscan2
- USH2A | c.10337C>A p.S3446Y | Missense Mutation (SNP) | VAF 125/469 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV56404503; called by muse, mutect2, varscan2
- USH2A | c.3144G>T p.L1048F | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV56404522; called by muse, mutect2, varscan2
- VPS13B | c.7864C>T p.P2622S | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV62150655; called by muse, mutect2
- YPEL3 | c.347A>C p.N116T (on ENST00000398838 / NM_001145524.2; = p.N154T on NM_031477.5) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV54222648; called by muse, mutect2, varscan2
- ZNF16 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV52764852, COSV52765200; called by muse, mutect2, varscan2
- ZNF254 | c.1382C>G p.P461R | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs748646434; called by muse, mutect2, varscan2
- ZNF432 | c.814A>G p.M272V | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs772108151, COSV55417719; called by muse, mutect2, varscan2
- ZNF521 | c.1328T>G p.L443W | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64129686; called by muse, mutect2, varscan2
- ZNF668 | c.1418A>T p.Q473L | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); catalogued as COSV56217007; called by muse, mutect2, varscan2
- ZNF668 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs750958929, COSV56217022; called by muse, mutect2, varscan2
- AP3B1 | c.2993-1G>T p.X998_splice | Splice Site (SNP) | VAF 83/164 reads (51%) | called by muse, mutect2, varscan2
- COL12A1 | c.1653del p.K552Nfs*11 | Frame Shift Del (DEL) | VAF 86/262 reads (33%) | called by mutect2, pindel, varscan2
- CPSF1 | c.4191C>A p.N1397K | Missense Mutation (SNP) | VAF 10/241 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); called by muse, mutect2
- DDX41 | c.374-1G>A p.X125_splice | Splice Site (SNP) | VAF 58/204 reads (28%) | called by muse, mutect2, varscan2
- DPF2 | c.1003_1005del p.T335del | In Frame Del (DEL) | VAF 33/66 reads (50%) | called by mutect2, pindel, varscan2
- ERG | c.1041G>C p.K347N (on ENST00000398919 / NM_001243428.1; = p.K323N on NM_004449.4) | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HEATR4 | c.2177T>C p.M726T | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IFNGR2 | c.700del p.C234Afs*17 | Frame Shift Del (DEL) | VAF 143/294 reads (49%) | called by mutect2, pindel, varscan2
- IGKV2D-30 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- IL26 | c.107del p.G36Efs*26 | Frame Shift Del (DEL) | VAF 53/155 reads (34%) | called by mutect2, pindel, varscan2
- IL27RA | c.1897C>G p.Q633E | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- KEAP1 | c.1676del p.I559Tfs*36 | Frame Shift Del (DEL) | VAF 47/88 reads (53%) | called by mutect2, pindel, varscan2
- LZTR1 | c.37del p.A13Lfs*12 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel
- MVP | c.2501A>C p.D834A | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NSMCE2 | c.651C>A p.H217Q | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- PCDHB6 | c.1485C>A p.H495Q | Missense Mutation (SNP) | VAF 32/522 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2
- PGA3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 48/628 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- RTP3 | c.129G>C p.M43I | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- STAT5B | c.2237+1G>A p.X746_splice | Splice Site (SNP) | VAF 46/174 reads (26%) | called by muse, mutect2, varscan2
- TENM2 | c.3719del p.P1240Qfs*29 (on ENST00000518659 / NM_001122679.2; = p.P1008Qfs*29 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 42/176 reads (24%) | called by mutect2, pindel, varscan2
- TPTE | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2
- TTN | c.11766_11767del p.K3922Nfs*4 (on ENST00000591111; = p.K3876Nfs*4 on NM_003319.4) | Frame Shift Del (DEL) | VAF 13/139 reads (9%) | called by mutect2, pindel, varscan2
- ADGRA1 | c.195G>C p.L65= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV66926599; called by muse, mutect2, varscan2
- BRINP1 | c.864C>T p.Y288= | Silent (SNP) | VAF 18/279 reads (6%) | called by muse, mutect2
- CHODL | c.744A>C p.G248= | Silent (SNP) | VAF 45/80 reads (56%) | catalogued as COSV53044671; called by muse, mutect2, varscan2
- COCH | c.126G>T p.L42= | Silent (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- CTDP1 | c.2094G>A p.Q698= | Silent (SNP) | VAF 8/232 reads (3%) | catalogued as COSV50006495; called by muse, mutect2
- DLGAP1 | c.474G>A p.P158= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs1424157355, COSV59821253; called by muse, mutect2, varscan2
- DTL | c.1500G>T p.S500= | Silent (SNP) | VAF 193/352 reads (55%) | catalogued as COSV65342877; called by muse, mutect2, varscan2
- FAM25C | c.174G>A p.G58= | Silent (SNP) | VAF 31/516 reads (6%) | catalogued as rs1555256358; called by muse, mutect2
- KIAA1549 | c.2256C>A p.T752= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- KREMEN2 | c.1293C>A p.S431= (on ENST00000303746 / NM_172229.3; = p.P405H on NM_024507.4) | Silent (SNP) | VAF 7/155 reads (5%) | catalogued as COSV51892071; called by muse, mutect2
- LNX2 | c.297T>C p.S99= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as rs1566123803, COSV60337359; called by muse, mutect2, varscan2
- LRP5 | c.3888C>T p.P1296= | Silent (SNP) | VAF 76/241 reads (32%) | catalogued as rs752439831, COSV53720053; ClinVar: likely benign; called by muse, mutect2, varscan2
- MRPS10 | c.549C>T p.H183= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV50002887; called by muse, mutect2, varscan2
- NEK11 | c.762G>A p.E254= | Silent (SNP) | VAF 53/132 reads (40%) | catalogued as rs758562940, COSV63582426; called by muse, mutect2, varscan2
- NISCH | c.1806C>T p.F602= | Silent (SNP) | VAF 35/166 reads (21%) | catalogued as COSV61901370; called by muse, mutect2, varscan2
- OR6B1 | c.594A>T p.V198= | Silent (SNP) | VAF 68/252 reads (27%) | catalogued as COSV68770415; called by muse, mutect2, varscan2
- PLIN5 | c.1062G>T p.A354= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV67850884, COSV67851276; called by muse, mutect2, varscan2
- PRRC2C | c.1764A>G p.E588= (on ENST00000367742; = p.E586= on NM_015172.4) | Silent (SNP) | VAF 60/238 reads (25%) | catalogued as COSV58909154; called by muse, mutect2, varscan2
- SLC5A7 | c.1656C>G p.T552= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV50896317; called by muse, mutect2, varscan2
- STRN3 | c.1452G>A p.R484= (on ENST00000357479 / NM_001083893.2; = p.R400= on NM_014574.4) | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as COSV62580986; called by muse, mutect2, varscan2
- TPMT | c.480A>C p.P160= | Silent (SNP) | VAF 107/267 reads (40%) | catalogued as COSV59429502; called by muse, mutect2, varscan2
- ZBTB10 | c.252C>T p.A84= | Silent (SNP) | VAF 49/161 reads (30%) | catalogued as rs1316770465, COSV66948172; called by muse, mutect2, varscan2
- AARS1 | c.1347+29C>G | Intron (SNP) | VAF 122/388 reads (31%) | catalogued as rs771468162; called by muse, mutect2, varscan2
- BTN2A3P | n.164A>C | RNA (SNP) | VAF 105/297 reads (35%) | called by muse, mutect2, varscan2
- CACNB1 | c.1332+107G>C | Intron (SNP) | VAF 15/32 reads (47%) | catalogued as rs748256606; called by muse, mutect2, varscan2
- CMSS1 | c.579+10G>T | Intron (SNP) | VAF 55/153 reads (36%) | called by muse, mutect2, varscan2
- COL20A1 | c.3295-98C>A | Intron (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- CTSA | c.1255-10G>A | Intron (SNP) | VAF 69/204 reads (34%) | called by muse, mutect2, varscan2
- DNPH1 | c.376+56C>A | Intron (SNP) | VAF 28/106 reads (26%) | catalogued as COSV52731838; called by muse, mutect2, varscan2
- EVX1 | chr7:27239304 T>A | 5'Flank (SNP) | VAF 52/178 reads (29%) | called by muse, mutect2, varscan2
- HOXA7 | chr7:27153153 G>A | 3'Flank (SNP) | VAF 4/11 reads (36%) | catalogued as rs974452439; called by muse, varscan2
- LTA | c.*167G>A | 3'UTR (SNP) | VAF 25/138 reads (18%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-10752A>G | Intron (SNP) | VAF 52/93 reads (56%) | catalogued as COSV57133369; called by muse, mutect2, varscan2
- MROH8 | c.109+2717_109+2720del | Intron (DEL) | VAF 38/200 reads (19%) | called by pindel, varscan2
- NAGLU | chr17:42547421 G>A | 3'Flank (SNP) | VAF 52/151 reads (34%) | catalogued as rs1357692934; called by muse, mutect2, varscan2
- NAGLU | chr17:42547422 C>A | 3'Flank (SNP) | VAF 50/148 reads (34%) | called by muse, mutect2, varscan2
- NKD1 | c.193-1446G>T | Intron (SNP) | VAF 15/242 reads (6%) | called by muse, mutect2
- PALLD | c.-9C>T | 5'UTR (SNP) | VAF 27/78 reads (35%) | catalogued as rs199737120, COSV54985309; called by muse, mutect2, varscan2
- PRRT1 | c.*21del | 3'UTR (DEL) | VAF 56/237 reads (24%) | called by mutect2, pindel, varscan2
- RNY4P30 | chr13:49890623 C>G | 5'Flank (SNP) | VAF 29/137 reads (21%) | called by muse, mutect2, varscan2
- RTN4 | c.3013+14956G>T | Intron (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
- SLC12A1 | c.-331G>A | 5'UTR (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2, varscan2
- SNORD115-41 | n.71del | RNA (DEL) | VAF 60/300 reads (20%) | called by mutect2, pindel, varscan2
- SP1 | c.-87G>T | 5'UTR (SNP) | VAF 45/125 reads (36%) | called by muse, mutect2, varscan2
- STON1 | chr2:48529536 C>T | 5'Flank (SNP) | VAF 100/313 reads (32%) | catalogued as rs1387375656; called by muse, mutect2, varscan2
- TMCC2 | c.748-12599T>C | Intron (SNP) | VAF 40/348 reads (11%) | called by muse, mutect2, varscan2
- TRIM5 | c.895+101G>C | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as COSV59901232; called by muse, mutect2, varscan2
- ZNF687 | chr1:151280247 G>T | 5'Flank (SNP) | VAF 11/172 reads (6%) | called by muse, mutect2
